Surgical pathology report (de-identified scan), TCGA case TCGA-06-0412, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0412-01A (Primary Tumor).

Patient Name:

MRN: ' .

Birth Date.

Sex: Fem

PATIENT NAME:

NO.:

AGE/SEX:

F

ACC. NO.:

ORDERING PHYSICIAN

PATH. NO:

NAME:

MED. REC. NO:

RECEIVE DATE:

PHYSICIAN:

PATHOLOGICAL DIAGNOSIS:BRAIN BIOPSY: GLIOBLASTOMA.

Operation/Specimen: Brain tumor.

Clinical History and Pre-Op Dx: Glioblastoma, recurrent brain tumor.
Primary.GROSS PATHOLOGY: The specimen labeled "brain biopsy", are several
0.2 to 0.5 cm. gray-white to pink wedge tissue. A portion of the
specimen has been examined by frozen section and submitted in cassette
1, the remaining tissue in cassettes 2 and 3.

INTRAOPERATIVE CONSULTATION, Frozen section diagnosis: Astrocytoma.

MICROSCOPIC: Sections reveal a high grade astrocytoma characterized by
hypercellularity, pleomorphism, marked vascular-endothelial hyperplasia
with thrombosis and patchy areas of necrosis. Infiltrating zones are
identified. One fragment of tumor tissue contains ependymal lining of
the ventricle.

TISSUE COMMITTEE CODE:

BILLING CODES:

Source: NCI Genomic Data Commons file 4700a457-391e-4281-b70a-58496825d11e (TCGA-06-0412.CDCE8B66-69B7-42EA-87D0-B561B85428E7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).